Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5744, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5744-01A (Primary Tumor).

TCGA - CH - 5744

Diagnosis

1. Predominantly poorly differentiated adenocarcinoma limited to the prostate on both sides (Gleason 4+3=7; tertiary grade 5) with the main focus in the right peripheral zone. Gleason 4 portions make up 70% and Gleason 5 portions account for less than 5% of the tumor.

Maximum tumor diameter 1.5 cm. No extraprostatic tumor growth. Multifocal tumor involvement of perineural sheaths. The main preparation shows tumor-free surgical margins.

In addition numerous foci of a prostatic intraepithelial neoplasia (high grade, PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of the prostatic urethra shows no dysplasia. Tumor-free, regularly structured seminal vesicle and seminal duct.

2. 2 tumor-free lymph nodes.
3. 1 tumor-free lymph node.
4. Tumor-free soft tissue with vessels and nerves.

Summary tumor classification

pT2c, maximum tumor diameter 1.5 cm, Gleason 4+3=7, tertiary grade 5, pN0 (0/3), R0.

Remark

In the corresponding frozen section analysis there was a right microfocal tumor involvement of the green labeled surgical resection margin (0.6 mm contact line).

Additional immunohistochemical studies will follow to clarify the vascular status. The results will be presented in a follow-up report.

Follow-up report

(Immunohistochemistry: D2-40, CD31).

In the additional immunohistochemical studies that have since been carried out in two representative tumor blocks, there is no evidence to suggest a tumor invasion of the vessels.

Otherwise, the concluding tumor classification is as follows:

pT2c, maximum tumor diameter 1.5 cm, Gleason 4+3=7, tertiary grade 5 (Gleason 4 = 70%, Gleason 5 <5%), L0, V0, pN0 (0/3), R0.

Source: NCI Genomic Data Commons file 4e4730bf-660d-402e-854c-84ede8cfcae8 (TCGA-CH-5744.797DB4C8-A9D9-4404-A520-9BE024CED9D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).